Somatic mutation profile of tumor specimen C3N-00857-01 (aliquot CPT0094350010) from CPTAC case C3N-00857, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,545 days).
Specimen C3N-00857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27acf5f6-daae-4734-b54c-a4e0d4dcf2b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00857-31 (Blood Derived Normal), aliquot CPT0094410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b072810-df43-4550-9d15-84973ce1f9b0

The open-access MAF lists 225 somatic variants for this specimen: 149 protein-altering or splice-affecting, 49 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 49, Intron 11, 3'UTR 8, Nonsense Mutation 7, Splice Site 5, 5'UTR 4, Splice Region 3, In Frame Ins 2, Frame Shift Ins 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs762139460, COSV61630540, COSV61632126; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 220/387 reads (57%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs766136483, COSV101036721; called by muse, mutect2, varscan2
- ABCD4 | c.1507-4A>G | Splice Region (SNP) | VAF 65/149 reads (44%) | catalogued as rs1354392618; called by muse, mutect2, varscan2
- AMZ1 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 101/328 reads (31%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1460771821; called by muse, mutect2, varscan2
- APOH | c.941A>T p.Q314L | Missense Mutation (SNP) | VAF 130/423 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV52773388; called by muse, mutect2, varscan2
- CCDC198 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99371111; called by muse, mutect2
- CCM2 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 92/636 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1355032027; called by muse, mutect2, varscan2
- CD81 | c.562-7C>T | Splice Region (SNP) | VAF 153/367 reads (42%) | catalogued as rs1490941091; ClinVar: likely benign; called by muse, mutect2, varscan2
- COX7A1 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs747380164, COSV99497037; called by muse, varscan2
- CRLF2 | c.351G>A p.L117= | Splice Region (SNP) | VAF 84/159 reads (53%) | catalogued as rs201965413; called by muse, mutect2, varscan2
- CSMD1 | c.5885G>A p.R1962H (on ENST00000520002; = p.R1961H on NM_033225.6) | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1190606096, COSV59363678; called by muse, mutect2, varscan2
- CTSL | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1486089016; called by muse, mutect2, varscan2
- CXorf21 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV100973348; called by muse, mutect2, varscan2
- DSG1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1331948792; called by muse, mutect2, varscan2
- EVI2A | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 161/470 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs559973245; called by muse, mutect2, varscan2
- FAT3 | c.10153C>T p.R3385W | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs200639035, COSV53189612; called by muse, mutect2, varscan2
- FOXN1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs551310590, COSV56883903; called by muse, mutect2, varscan2
- FRY | c.8487G>C p.Q2829H | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV66511808; called by muse, mutect2, varscan2
- GALR1 | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 82/415 reads (20%) | catalogued as COSV55317496; called by muse, mutect2, varscan2
- GOLGA8Q | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 32/898 reads (4%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.997); catalogued as rs1488388219; called by muse, mutect2
- KCNA1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 68/764 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs1361446640, COSV66836423, COSV66837186; called by muse, mutect2
- KDM3A | c.2327C>A p.A776D | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs551221346, COSV100459913; called by muse, mutect2, varscan2
- KDM5A | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 84/1031 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV66990199, COSV66994241, COSV66995937; called by muse, mutect2
- KIAA1549 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 84/315 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs778018617, COSV54306017; called by muse, mutect2, varscan2
- KIF14 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs1034376559, COSV66263257; called by muse, mutect2, varscan2
- MTARC2 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.173); catalogued as rs749638702; called by muse, mutect2, varscan2
- MUC12 | c.5822G>C p.R1941T (on ENST00000379442; = p.R1798T on NM_001164462.1) | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.234); catalogued as rs1398226236; called by muse, mutect2
- NMD3 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63619752; called by muse, mutect2, varscan2
- NRN1L | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs371968237; called by muse, mutect2, varscan2
- OLFM1 | c.1232C>T p.T411M (on ENST00000371793 / NM_001282611.2; = p.T393M on NM_014279.5) | Missense Mutation (SNP) | VAF 173/246 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767622547, COSV53277197, COSV53278980; called by muse, mutect2, varscan2
- OR6X1 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60009314, COSV60010154; called by muse, mutect2, varscan2
- OR8I2 | c.254T>A p.F85Y | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100135855; called by muse, mutect2, varscan2
- OR8S1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | PolyPhen benign (0); catalogued as rs373769388, COSV59599539; called by muse, mutect2, varscan2
- PARP10 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 17/593 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1015498888; called by muse, mutect2
- PBX3 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as COSV100655248; called by muse, mutect2, varscan2
- PCDHA10 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as rs782574934, COSV56538654; called by muse, mutect2
- PCSK2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV52736448; called by muse, mutect2, varscan2
- PDE4D | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs917710480; called by muse, mutect2, varscan2
- PLCXD3 | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 76/301 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1236501969; called by muse, mutect2, varscan2
- PPL | c.3379G>A p.E1127K | Missense Mutation (SNP) | VAF 79/512 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs769930858, COSV52167388; called by muse, mutect2, varscan2
- PRR12 | c.2690C>A p.T897N (on ENST00000615927; = p.T1718N on NM_020719.3) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as rs753470902; called by muse, mutect2
- RALY | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 94/178 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs775046582; called by muse, mutect2
- RASAL3 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 58/586 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753396666; called by muse, mutect2
- RNF44 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs766556120, COSV51269873; called by muse, mutect2
- RTL1 | c.3724C>T p.R1242C | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs765417912, COSV66017009; called by muse, mutect2
- SH3TC2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 116/531 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs369977771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A11 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs200088797; called by muse, mutect2, varscan2
- ST3GAL3 | c.529A>G p.I177V (on ENST00000361392 / NM_174964.4; = p.I162V on NM_006279.5) | Missense Mutation (SNP) | VAF 159/378 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as rs1224925138; called by muse, mutect2, varscan2
- SV2C | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV59217733; called by muse, mutect2, varscan2
- SYF2 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197929769; called by muse, mutect2, varscan2
- SZT2 | c.7909G>A p.D2637N (on ENST00000634258 / NM_001365999.1; = p.D2580N on NM_015284.4) | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.16); catalogued as rs1335868917, COSV65167473; called by muse, mutect2, varscan2
- TKTL1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782370876; called by muse, mutect2, varscan2
- TRIP4 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.409); catalogued as rs1271138037; called by muse, mutect2, varscan2
- TTPAL | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99375563; called by muse, mutect2, varscan2
- WFDC1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs757803907; called by muse, mutect2, varscan2
- ZNF850 | c.1240A>T p.I414F | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV74024575; called by muse, mutect2, varscan2
- ABCA13 | c.13837A>C p.T4613P | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA6 | c.791+2T>A p.X264_splice | Splice Site (SNP) | VAF 27/80 reads (34%) | called by muse, varscan2
- ACAT2 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADRA1B | c.1427dup p.K477Qfs*78 | Frame Shift Ins (INS) | VAF 57/145 reads (39%) | called by mutect2, pindel, varscan2
- ANAPC2 | c.1520G>C p.S507T | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- ANK2 | c.4864G>C p.D1622H | Missense Mutation (SNP) | VAF 94/288 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ANO2 | c.1494C>A p.S498R (on ENST00000356134 / NM_001278597.3; = p.S502R on NM_001278596.3) | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2
- ARID1B | c.2243-1G>C p.X748_splice | Splice Site (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- ARMC3 | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ARSA | c.854+2_854+48del p.X285_splice | Splice Site (DEL) | VAF 100/470 reads (21%) | called by mutect2, pindel
- BCR | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 76/416 reads (18%) | called by muse, mutect2, varscan2
- C11orf71 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASC3 | c.1409A>T p.N470I | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- CBARP | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CELSR1 | c.8660A>G p.K2887R | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CEP250 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CHADL | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- COPZ1 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, varscan2
- COQ6 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 36/877 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- CORO6 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DAG1 | c.2633C>G p.S878C | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCTN2 | c.203-1G>A p.X68_splice (on ENST00000548249 / NM_001261413.2; = p.X73_splice on NM_006400.4) | Splice Site (SNP) | VAF 115/222 reads (52%) | called by muse, mutect2, varscan2
- ELOVL4 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 109/357 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, varscan2
- EXT1 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 16/529 reads (3%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.732); called by muse, mutect2
- F13B | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 83/500 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FBXO41 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCAR | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 213/499 reads (43%) | called by muse, mutect2, varscan2
- FGA | c.1029T>A p.S343R | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- FMO4 | c.1458C>G p.I486M | Missense Mutation (SNP) | VAF 112/560 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FMOD | c.686A>T p.D229V | Missense Mutation (SNP) | VAF 77/572 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FRK | c.10_13dup p.C5Yfs*27 | Frame Shift Ins (INS) | VAF 16/140 reads (11%) | called by mutect2, pindel, varscan2
- FSTL5 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- FUCA1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- GDF11 | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2141A>G p.E714G | Missense Mutation (SNP) | VAF 278/1496 reads (19%) | SIFT deleterious (0); called by muse, varscan2
- HDLBP | c.2366_2368dup p.E789_L790insQ | In Frame Ins (INS) | VAF 43/170 reads (25%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.1372C>A p.Q458K | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, varscan2
- JAM3 | c.723C>G p.N241K | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- KDM5C | c.3251A>G p.K1084R | Missense Mutation (SNP) | VAF 143/213 reads (67%) | SIFT tolerated (0.89); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- KIF15 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KRTAP13-2 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- LCOR | c.3712C>G p.H1238D | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LILRB5 | c.1539-1G>A p.X513_splice (on ENST00000449561 / NM_001081442.3; = p.X512_splice on NM_006840.5) | Splice Site (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- MACF1 | c.14930C>G p.S4977C (on ENST00000372915; = p.S2910C on NM_012090.5) | Missense Mutation (SNP) | VAF 30/414 reads (7%) | called by muse, mutect2
- MAPK8IP3 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MEI1 | c.2705C>G p.S902* | Nonsense Mutation (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- MPDZ | c.4138A>C p.I1380L | Missense Mutation (SNP) | VAF 199/268 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MUC2 | c.2986G>C p.D996H | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYOM3 | c.3009C>G p.N1003K | Missense Mutation (SNP) | VAF 177/416 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- N4BP2 | c.3245_3247dup p.E1082_L1083insQ | In Frame Ins (INS) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- NRXN3 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 174/326 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OPRL1 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OR56B4 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, varscan2
- OR9G1 | c.322T>A p.Y108N | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.466); called by muse, mutect2
- PARP10 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PCDH9 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDHB7 | c.2135G>T p.C712F | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PCLO | c.14822G>T p.S4941I | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2
- PDCD1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PDZD2 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- PGM1 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 94/514 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PKN2 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PLXND1 | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 16/269 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRRC2A | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- PRRC2B | c.2752T>G p.W918G | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRE | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- QRSL1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RADIL | c.1559T>C p.I520T | Missense Mutation (SNP) | VAF 47/450 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- REXO2 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD7 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SHANK2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- SLC25A42 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SNX25 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- SNX25 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPG7 | c.1114G>C p.V372L (on ENST00000268704; = p.V379L on NM_003119.4) | Missense Mutation (SNP) | VAF 108/402 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SRBD1 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ST14 | c.621G>C p.Q207H | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- STK32C | c.1234A>T p.R412W | Missense Mutation (SNP) | VAF 105/179 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- TGFB3 | c.1238G>C p.*413Sext*16 | Nonstop Mutation (SNP) | VAF 282/598 reads (47%) | called by muse, mutect2, varscan2
- TNXB | c.10420G>T p.G3474W (on ENST00000647633; = p.G3227W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM4 | c.3475_3482del p.L1159Afs*22 | Frame Shift Del (DEL) | VAF 174/579 reads (30%) | called by mutect2, pindel, varscan2
- TRPT1 | c.664C>T p.P222S (on ENST00000317459 / NM_001160393.1; = p.P173S on NM_031472.4) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TUBB4B | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 317/524 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- VPS13D | c.8645A>T p.K2882M | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR7 | c.3901C>G p.R1301G | Missense Mutation (SNP) | VAF 73/317 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- YTHDC1 | c.400T>A p.C134S | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, varscan2
- ZBTB3 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZFP28 | c.2567C>A p.P856H | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ZIC5 | c.740C>G p.T247S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF579 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- ZNF582 | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ZNF644 | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDH22 | c.36G>T p.A12= | Silent (SNP) | VAF 90/194 reads (46%) | called by muse, mutect2, varscan2
- CEP152 | c.2241C>T p.L747= | Silent (SNP) | VAF 25/556 reads (4%) | called by muse, mutect2
- DACH2 | c.384C>T p.V128= | Silent (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- DCBLD1 | c.2013C>T p.V671= | Silent (SNP) | VAF 21/516 reads (4%) | called by muse, mutect2
- DHX16 | c.1530C>T p.D510= | Silent (SNP) | VAF 26/236 reads (11%) | catalogued as rs760543641; called by muse, mutect2
- DOCK4 | c.1461C>T p.F487= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as rs1402210223, COSV101455774; called by muse, mutect2, varscan2
- EBAG9 | c.222A>G p.E74= | Silent (SNP) | VAF 124/322 reads (39%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.351C>T p.N117= | Silent (SNP) | VAF 406/535 reads (76%) | called by muse, mutect2, varscan2
- EPHA10 | c.684C>T p.S228= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs1348822629; called by muse, mutect2, varscan2
- ESYT3 | c.2064C>T p.I688= | Silent (SNP) | VAF 31/471 reads (7%) | called by muse, mutect2
- EVA1A | c.159G>T p.L53= | Silent (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- EVX2 | c.93G>A p.S31= | Silent (SNP) | VAF 79/261 reads (30%) | called by muse, mutect2, varscan2
- EXOC7 | c.250C>T p.L84= | Silent (SNP) | VAF 69/231 reads (30%) | called by muse, mutect2, varscan2
- F8 | c.4140G>A p.E1380= | Silent (SNP) | VAF 72/154 reads (47%) | catalogued as COSV64278612; called by muse, varscan2
- FLT1 | c.1773A>G p.L591= | Silent (SNP) | VAF 80/471 reads (17%) | called by muse, varscan2
- FTO | c.552C>T p.S184= | Silent (SNP) | VAF 500/1077 reads (46%) | catalogued as rs1415149744; called by muse, mutect2, varscan2
- FZD1 | c.1656C>T p.I552= | Silent (SNP) | VAF 70/1326 reads (5%) | catalogued as rs1373346273, COSV55310156; called by muse, mutect2
- GMEB1 | c.639G>A p.T213= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs923879513, COSV53796384; called by muse, mutect2, varscan2
- GPR75 | c.252G>A p.L84= | Silent (SNP) | VAF 70/434 reads (16%) | called by muse, mutect2, varscan2
- HS3ST2 | c.444C>T p.H148= | Silent (SNP) | VAF 172/517 reads (33%) | called by muse, mutect2, varscan2
- KCNK10 | c.1182C>T p.P394= | Silent (SNP) | VAF 50/259 reads (19%) | catalogued as rs369723489; called by muse, mutect2, varscan2
- LAMA3 | c.6297G>A p.Q2099= (on ENST00000313654 / NM_198129.4; = p.Q490= on NM_000227.6) | Silent (SNP) | VAF 152/351 reads (43%) | called by muse, mutect2, varscan2
- MIEN1 | c.276C>T p.A92= | Silent (SNP) | VAF 61/411 reads (15%) | called by muse, mutect2, varscan2
- MPEG1 | c.928C>T p.L310= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- MYO16 | c.2025T>C p.I675= | Silent (SNP) | VAF 52/242 reads (21%) | called by muse, mutect2, varscan2
- NCOA6 | c.4386G>A p.G1462= | Silent (SNP) | VAF 52/304 reads (17%) | called by muse, mutect2, varscan2
- NID1 | c.3354G>A p.A1118= | Silent (SNP) | VAF 63/362 reads (17%) | catalogued as rs375679956; called by muse, mutect2, varscan2
- NLGN4X | c.2016C>T p.S672= | Silent (SNP) | VAF 34/323 reads (11%) | catalogued as COSV52009587, COSV99321518; called by muse, mutect2, varscan2
- NOTCH3 | c.447C>T p.G149= | Silent (SNP) | VAF 52/406 reads (13%) | called by muse, mutect2, varscan2
- NPFFR2 | c.1035A>G p.G345= | Silent (SNP) | VAF 79/303 reads (26%) | called by muse, mutect2, varscan2
- OTOF | c.5529C>T p.F1843= (on ENST00000272371 / NM_194248.3; = p.F1076= on NM_004802.4) | Silent (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- POTEH | c.258C>T p.H86= | Silent (SNP) | VAF 169/1352 reads (13%) | catalogued as rs370869918; called by muse, varscan2
- PRPF31 | c.1191C>T p.G397= | Silent (SNP) | VAF 90/749 reads (12%) | called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2, varscan2
- ROS1 | c.5649T>C p.H1883= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as rs368278112; called by muse, mutect2, varscan2
- SGCE | c.1080C>T p.P360= (on ENST00000647096; = p.P324= on NM_003919.3) | Silent (SNP) | VAF 232/1364 reads (17%) | catalogued as rs1490533382; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A10 | c.198G>A p.L66= | Silent (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.210C>A p.V70= | Silent (SNP) | VAF 56/242 reads (23%) | called by muse, mutect2, varscan2
- SPATA20 | c.1395G>A p.L465= (on ENST00000356488 / NM_001258372.1; = p.L481= on NM_022827.4) | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- SPTA1 | c.4563C>G p.P1521= | Silent (SNP) | VAF 91/637 reads (14%) | called by muse, mutect2, varscan2
- STAG2 | c.2196C>T p.H732= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as rs763447297, COSV54363476; called by muse, mutect2, varscan2
- STIL | c.2064G>A p.P688= | Silent (SNP) | VAF 239/555 reads (43%) | catalogued as rs138834578; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TACC1 | c.165G>A p.S55= | Silent (SNP) | VAF 195/275 reads (71%) | catalogued as COSV52524979; called by muse, mutect2, varscan2
- TSPYL5 | c.822G>A p.L274= | Silent (SNP) | VAF 31/830 reads (4%) | called by muse, mutect2
- TTN | c.6546T>C p.D2182= (on ENST00000591111; = p.D2136= on NM_003319.4) | Silent (SNP) | VAF 63/198 reads (32%) | called by muse, mutect2, varscan2
- UNC5A | c.1257C>A p.A419= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- WDR86 | c.138C>T p.D46= | Silent (SNP) | VAF 26/124 reads (21%) | called by muse, mutect2, varscan2
- WNK2 | c.2706C>T p.A902= | Silent (SNP) | VAF 86/368 reads (23%) | catalogued as rs368180906; called by muse, mutect2, varscan2
- ZFYVE9 | c.1143T>C p.L381= | Silent (SNP) | VAF 75/265 reads (28%) | catalogued as COSV99819769; called by muse, mutect2, varscan2
- ADAM15 | c.80-16G>A | Intron (SNP) | VAF 166/341 reads (49%) | catalogued as rs765653167; called by muse, mutect2, varscan2
- ATP6V0E2 | c.-13C>T | 5'UTR (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- CCM2 | chr7:44999836 G>A | 5'Flank (SNP) | VAF 17/81 reads (21%) | catalogued as rs1405253123; called by muse, mutect2, varscan2
- CCNYL2 | n.780C>G | RNA (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- DAG1 | c.*252C>G | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, varscan2
- DNAJC19 | c.*449C>T | 3'UTR (SNP) | VAF 939/1823 reads (52%) | called by muse, mutect2, varscan2
- FPGS | c.-30G>A | 5'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- GAP43 | c.31-12129T>G | Intron (SNP) | VAF 38/380 reads (10%) | called by muse, mutect2
- GK5 | c.1441+16A>T | Intron (SNP) | VAF 126/455 reads (28%) | called by muse, mutect2, varscan2
- HNF4A | c.1129+25G>A | Intron (SNP) | VAF 142/292 reads (49%) | catalogued as rs768898137; called by muse, mutect2, varscan2
- IMPDH1 | c.-27T>C | 5'UTR (SNP) | VAF 132/286 reads (46%) | called by muse, mutect2, varscan2
- MERTK | c.2190-802T>G | Intron (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378126 C>T | 5'Flank (SNP) | VAF 18/116 reads (16%) | catalogued as rs746207708; called by muse, mutect2, varscan2
- MIR516B2 | n.28G>A | RNA (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- MRPL50 | c.*1034C>G | 3'UTR (SNP) | VAF 32/147 reads (22%) | called by muse, mutect2, varscan2
- MSI2 | c.727+4522C>T | Intron (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.618-3054G>T | Intron (SNP) | VAF 416/610 reads (68%) | called by muse, mutect2, varscan2
- NR3C2 | c.*579C>A | 3'UTR (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- PDLIM2 | c.541-9T>G | Intron (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- RAB28 | c.-8G>T | 5'UTR (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- RP9 | c.*47G>T | 3'UTR (SNP) | VAF 57/344 reads (17%) | called by muse, mutect2, varscan2
- SEM1 | c.*33T>G | 3'UTR (SNP) | VAF 28/511 reads (5%) | called by muse, mutect2
- TPO | c.482+2450C>G | Intron (SNP) | VAF 31/206 reads (15%) | catalogued as COSV100221557; called by muse, mutect2, varscan2
- TRPM4 | c.3329-27G>A | Intron (SNP) | VAF 108/290 reads (37%) | called by muse, mutect2, varscan2
- TYRO3 | c.*15G>T | 3'UTR (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2
- ZAP70 | c.1623+41G>T | Intron (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- ZBTB40 | c.*49G>T | 3'UTR (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
